Somatic mutation profile of tumor specimen TARGET-20-PARYGA-03A (aliquot TARGET-20-PARYGA-03A-01D) from TARGET case TARGET-20-PARYGA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,916 days).
Specimen TARGET-20-PARYGA-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eeba95f0-7027-4e5f-86d3-9cde5e5c0088.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARYGA-14A (Bone Marrow Normal), aliquot TARGET-20-PARYGA-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ac026fc-f581-4b8a-8092-b5874477f04e

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 81/232 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYC | c.176C>A p.P59Q (on ENST00000377970; = p.P74Q on NM_002467.6) | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2, varscan2
- RUNX1 | c.1024_1027dup p.A343Vfs*231 (on ENST00000344691 / NM_001001890.3; = p.A370Vfs*231 on NM_001754.5) | Frame Shift Ins (INS) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
